Gene-level copy-number profile of tumor specimen RC-B6SM-TTP1-A from RC case RC-B6SM, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Angioimmunoblastic T-cell lymphoma; Tissue or organ of origin: Lymph nodes of axilla or arm; Age at diagnosis: 78.2 years (28,564 days).
Specimen RC-B6SM-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d022fd77-8f8e-4622-8574-b87dc5772a82.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B6SM-NB1-A; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/551aff55-f75f-4a32-8b6c-8dc292adc7ac

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 109; copy number 1: 700; copy number 2: 57,548; copy number 3: 30.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,281,105–22,552,156, 76 genes (within-gene range 0–2) (broad region; genes not listed).
- chr15:21,980,277–22,202,734, 17 genes: OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10, IGHV1OR15-1, IGHV1OR15-3, IGHV4OR15-8, IGHV1OR15-4, AC025884.3.
- chr15:32,384,937–32,587,613, 15 genes (within-gene range 0–2): DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 700. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
